Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00J, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00J-01A (Primary Tumor).

Sample ID #

Diagnosis:

Right hemicolectomy specimen with tumor-free oral and aboral resection margins, with two tubular colon mucosal adenomas with up to moderate dysplasia (synonym: low-grade intra-epithelial neoplasia) and under inclusion of an ulcerated, poorly differentiated, partially mucinous adenocarcinoma in the caecum and ascending colon, with penetration of all layers of the wall, penetration of the peritoneum and with two regional lymph node metastases (G3, pT4 L1 V0 pN1 2/24).

1CD-0-3

adenocarcinoma, mucinous, NOS 8480/3

Site: ascending colon C18.2 N
3/29/11

Primary Discrepancy		

5/10/11

Source: NCI Genomic Data Commons file 093e0e44-1c1c-4549-83e1-2131a89bd26c (TCGA-AA-A00J.A207E6D8-FF21-49FD-A84B-D941C85A8631.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).